Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ADJ2, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ADJ2-TTM1-A (Metastatic).

[page 1 of 15]
Result Information

SURGICAL PATHOLOGY

Result Information

Status
EditedProvider Status
Reviewed

Result Date - [REDACTED] +17

Component Results

Component

Report, pathology

Case # [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS:

REVISED REPORT. Insertions are designated by {{ }}.
<Deletions> marked by <> are documented below

Lung, left, needle core biopsies:

- poorly differentiated malignant neoplasm

{{ most consistent with metastatic leiomyosarcoma }}

Amendments:

Amended: [REDACTED]

Amendment Comment:

consultation results

Previous Signout Date: [REDACTED] +3

Microscopic Description:

Sections demonstrate cores of tissue which consist almost predominantly of tumor. The neoplasm consists of highly pleomorphic cells which vary from small to giant in size with variable shaped nuclei. The nuclei demonstrate nucleoli, although inconsistently, and some show intranuclear inclusions. The tumor is predominantly present in cords and sheets with no definitive glandular or squamous differentiation identified. No pigmentation is seen.

{{Immunostains demonstrate that the tumor is positive for smooth muscle actin, with very focal desmin positivity, diffuse estrogen receptor and Mib-1 (30-40%). Pertinent negative markers include: CK7, CK20, CK 5/6, P63, TTF-1, S100, CDX-2, CD34 and CD117. A mucicarmine special stain is negative.

The slides, including current immunostains, and a block from this current case as well as from the hysterectomy specimen

[REDACTED] were sent to [REDACTED]

[REDACTED] for review. In their opinion, the findings in

[REDACTED] are most consistent with a leiomyosarcoma based on the increased tumor cellularity, tumor cell necrosis, diffuse cytologic

[page 2 of 15]
atypia and nuclear pleomorphism with enlarged, hyperchromatic nuclei. In their view, dealing with atypical smooth muscle tumors can be difficult in differentiating pseudomitoses from true mitotic figures in establishing the diagnosis of leiomyosarcoma. The current lung sampling has similar morphologic features to those in the hysterectomy specimen and in concert with the immunostains, represent metastases from the uterine leiomyosarcoma.}}

THE FOLLOWING TEXT IS DELETED FROM THE ORIGINAL REPORT:

<1> Immunostains are being performed and will be reported in an addendum.

Studies:

The immunohistochemistry test was developed and its performance characteristics determined by [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing. [REDACTED]

Clinical History:

Tissue: Left lung fine needle aspiration biopsy under CT guidance.

Clinical History: History of malignancy, multiple pulmonary masses. Biopsy of left lung mass.

Gross Description

Received is a single container labeled [REDACTED]

Received in formalin are three soft rods of tan to pink tissue varying from 12 to 14 mm in length and averaging 1 mm in diameter. The entire specimen is submitted for histologic evaluation. [REDACTED]
XX

Specimen(s) Received

Lung, Needle Biopsy - L.

[page 3 of 15]
+0

Collected: [REDACTED]

Case #: [REDACTED]

Surgical Pathology Report

* Amended *

+0

Lab and Collection

SURGICAL PATHOLOGY (Order # [REDACTED] on [REDACTED] - Lab and Collection Information

Reviewed by List**Patient Release Status:**

This result is not viewable by the patient.

Order Information

SURGICAL PATHOLOGY [REDACTED]

Encounter[View Encounter](#)**Priority and Order Details**

Priority	Class
Routine	Normal

[page 4 of 15]
SURGICAL PATHOLOGY

+0

[Click Here to re-print the order report](#)

SURGICAL PATHOLOGY

+0

[page 5 of 15]
Results

Encounter

View Encounter

PACS Images

Show images for CT THORAX, W CONTRAST

Future Appts

Result Information

	Status	Provider Status
Normal		Open

Study Result

-11

-11

CT OF THE CHEST

CLINICAL INFORMATION:

Bilateral pulmonary nodules seen on CT of the abdomen and pelvis, pulmonology requests contrast CT.

PROCEDURE:

5 mm images were obtained through the chest during intravenous infusion of 100 mL of Omnipaque 300 without reported complication. Overlapping 5 x 2.5 mm lung algorithm images and thin sliced coronal reformatted images were provided.

-16

FINDINGS:

Comparison is made with the recent abdomen CT. The distal esophagus is abnormal. There is a mixed attenuation mass in the lower esophagus measuring about 6.1 x 6.3 cm. It was present previously and looks the same. It could be a complicated hiatal hernia, but given the abnormalities in the lung parenchyma, a neoplasm in the distal esophagus or proximal stomach needs to be excluded by gastroenterology. Patient has multiple bilateral pulmonary parenchymal masses. The largest one on the left is in the upper lobe and measures on lung windows about 2.4 x 4.4 cm. The largest on the right is in the middle lobe and it measures on the lung windows of about 4.7 x 4.4 cm. There are other variably sized masses and nodules throughout the lungs. No pleural effusions. No inflammatory looking infiltrates. No evidence of hilar or mediastinal lymphadenopathy.

There is no evidence of breast mass or extrathoracic adenopathy.

IMPRESSION:

1. Complex distal esophageal mass needs to be further evaluated by gastroenterology.
2. Bilateral pulmonary parenchymal masses consistent with metastatic disease.

D:
T:
D:
T:

Result History

CT THORAX, W CONTRAST

- Order Result History Report

[page 6 of 15]
Imaging Information

-11

-11

Exam Information

Performed Procedure
CT THORAX W CONTRAST

Study Status
Final

Begin Time

End Time

Order

CT THORAX, W CONTRAST

Print Result Report

report

Order

CT THORAX, W CONTRAST

[EXPIRED] CT THORAX, W CONTRAST

Order #

Spec.

Original Order Name (If blank, same as above):

CT THORAX, W CONTRAST

Encounter

View Encounter

Future Order Information

Expected

Expires

Comments

DIAGNOSIS: bilat pulm nodules seen on ct abd/pelvis. (sign/symptom/ location, which has an ICD-9 code)CLINICAL CONCERN: would like ct chest with iv contrast within 1 week or so to look for masses.Please wait for 2 days before doing study as she just had a ct abd with iv contrast.Thank you (differential diagnosis or r/o)This study results in a large dosage of radiation, equal to approximately 100 CXRs. Repeated exams in young people, especially 20-40 yo women, increases the chance of radiation induced tumors. Consider alternative tests; avoid repeated exams if not indicated.WEIGHT: 175 lbs

[page 7 of 15]
Scheduling Instructions

** CT SCHEDULING INSTRUCTIONS **

- * Your provider has ordered a CT Scan. The CT department will call you to schedule your appointment.
- * If you had a CT exam today as a result of your ER visit, please disregard these instructions.

** IMPORTANT INFORMATION FOR**

PATIENTS TAKING METFORMIN (GLUCOPHAGE)

Your provider has scheduled you for an exam (cat scan, IVP, or angiogram). It may require the use of iodine contrast material. This will be determined by the Radiologist the day of your exam.

DAY OF THE EXAM:

1. Diabetic patients taking the medication called Glucophage (Metformin), will be asked to temporarily discontinue Metformin after administration of IV contrast.

2. Follow the appropriate instructions as outlined below:

IF YOU RECEIVE IODINE CONTRAST MATERIAL as part of the x-ray exam, Follow these instructions:

1. Day of exam: Do not take glucophage (Metformin) after your CT and for two more days after following injection of iodine contrast material. Continue to check your Glucose closely.

2. Two days after exam: Go to the [REDACTED] lab for a blood test called a "creatinine level". This blood test will evaluate your kidney function. Your provider will order this blood test for you. Use the [REDACTED] lab most convenient.

Medication Management will let you know when to restart your Metformin. If you've not heard from them please call [REDACTED]

Order Tracking Information

CT THORAX, W CONTRAST [REDACTED]

[page 8 of 15]
Results CT CHEST ABDOMEN AND PELVIS, W CONTRAST (Accession [REDACTED])

Encounter

View Parent Encounter

PACS Images

Show images for CT CHEST ABDOMEN AND PELVIS, W CONTRAST

Future Appnts

Result Information

Status	Provider Status
Normal	Reviewed

Study Result

+572

+572

CAT SCAN OF THE CHEST, ABDOMEN, AND PELVIS WITH CONTRAST

INDICATION FOR EXAMINATION:

History of leiomyosarcoma, metastatic to lung. Evaluate for response. Please compare to prior.

TECHNIQUE:

Oral contrast had been administered. 5 mm images were obtained through the chest, abdomen, and pelvis during intravenous infusion of 100 mL of Isovue 370 without reported complication. Overlapping 5 x 2.5 mm lung algorithm images and thin sliced coronal reformatted images were provided.

COMPARISON:

Current examination is compared with previous CAT scan of the neck, chest, abdomen, and pelvis performed with IV contrast from [REDACTED] +304

FINDINGS:

CHEST CAT SCAN: All of the previously demonstrated bilateral pulmonary nodules have resolved since the [REDACTED] exam. Small left pleural effusion has resolved. Mild left basilar pleural thickening has nearly completely resolved with very subtle residual pleural irregularity at the posterior left pleura on images 60 through 81 of series A2 with lung windows. Right-sided central venous port is again demonstrated with the tip of the catheter in the mid superior vena cava in appropriate central position. No evidence of axillary, hilar, nor mediastinal adenopathy. Moderate hiatal hernia appears similar to that of the previous exam. Previously demonstrated tiny right pleural effusion has resolved. Retroesophageal right subclavian artery, a congenital variant of normal, is again noted incidentally.

ABDOMINAL CAT SCAN: Subtle low attenuation focus in the medial left lobe of the liver is much less well-defined and probably represents a variant of vascular anatomy but in any event appears less prominent than on the previous exam. Otherwise, the liver appears fairly homogeneous and unremarkable. Gallbladder, spleen, and pancreas all appear unremarkable. Small peripheral cyst, left posterior mid kidney, appears stable. Adrenal glands and kidneys otherwise appear unremarkable. Visualized bowel loops in the abdomen and the appendix appear unremarkable. No dilated large or small bowel loops. No evidence of adenopathy within the abdomen or the retroperitoneum. Incidental note is again made of hepatic flexure anterior to the right lobe of the liver, a variant of normal, referred to as Chilaiditi's syndrome. Scattered

[page 9 of 15]
[REDACTED]

atherosclerotic vascular calcifications throughout the abdominal aorta are again demonstrated without evidence of abdominal aortic aneurysm, dissection, or periaortic inflammatory changes.

PELVIC CAT SCAN: Scattered diverticula within the left colon and sigmoid colon without evidence of diverticulitis. No evidence of adenopathy, soft tissue masses, or abnormal fluid collections within the pelvis. The remaining bowel loops in the pelvis appear unremarkable and nondistended. Unopacified bladder appears unremarkable.

Review of bone windows demonstrates no suspicious lytic or sclerotic bony lesions.

IMPRESSIONS:

Resolution of previously demonstrated bilateral pulmonary nodules and bilateral pleural effusions when compared with the [REDACTED] exam. Only mild residual left posterior pleural thickening remains. Remainder of the CAT scan of the chest, abdomen, and pelvis appears otherwise unremarkable. No evidence of new disease or disease progression within the chest, abdomen, or the pelvis radiographically.

Result History

CT CHEST ABDOMEN AND PELVIS, W CONTRAST
Report

[REDACTED] - Order Result History

+572

Imaging Information

Exam Information

Performed Procedure
CT CHEST ABD AND PELVIS W CONTRAST

Study Status
Final +572

Begin Time

End Time

[REDACTED] +572

Order

CT CHEST ABDOMEN AND PELVIS, W CONTRAST [REDACTED]

Print Result Report

report

Order

CT CHEST ABDOMEN AND PELVIS, W CONTRAST [REDACTED]

CT CHEST ABDOMEN AND PELVIS, W CONTRAST [REDACTED]

Order #:

Spec.

Encounter

View Parent Encounter

[REDACTED]

[page 10 of 15]
Order Information

Assoc. Dx

CA METASTATIC TO LUNG

Priority and Order Details

Priority	Order Status	Class
Routine	Completed	Normal

Order Questions

Question	Answer	Comment
Does patient have known reaction to IV contrast? (If yes, describe rx in comments and order pretreatment Smart RX)	NO	

Comments

CLINICAL CONCERN: Please evaluate for response. Please compare to priors.
(differential diagnosis or r/o)

This study results in a large dosage of radiation, equal to approximately 100 CXRs. Repeated exams in young people, especially 20-40 yo women, increases the chance of radiation induced tumors. Consider alternative tests; avoid repeated exams if not indicated.

Wt Readings from Last 1 Encounters:

+511 : 160 lb 9.6 oz (72.848 kg)

Scheduling Instructions

** CT SCHEDULING INSTRUCTIONS **

Follow the appropriate instructions as outlined below:

[page 11 of 15]
Order Tracking Information

CT CHEST ABDOMEN AND PELVIS, W CONTRAST (Order

+572

[page 12 of 15]
Results CT NECK CHEST ABD AND PELVIS W CONTRAST (Accession [REDACTED])

Encounter

View Parent Encounter

PACS Images

Show images for CT NECK CHEST ABD AND PELVIS W CONTRAST

Future Appts

Result Information

Status

Provider Status

Final result [REDACTED]

Reviewed

Study Result +1782

EXAM: CT NECK CHEST ABD AND PELVIS W CONTRAST

DATE: [REDACTED] +1781

HISTORY: 67-year-old female with history of metastatic leiomyosarcoma.

COMPARISON:

+1775

Chest radiograph, [REDACTED] +572

CT chest, abdomen, and pelvis, [REDACTED]

CT neck, chest, abdomen, and pelvis, [REDACTED] +304

TECHNIQUE: 2.5 mm contiguous axial CT images obtained through the neck, chest, abdomen, and pelvis following the uneventful IV administration of 100 milliliters Isovue 370 and oral contrast. In addition, 1.25 mm axial CT images were acquired through the chest using lung algorithm. Sagittal and coronal reformats were also obtained.

FINDINGS:

NECK:

There is no cervical lymphadenopathy or abnormal soft tissue neck mass to indicate metastatic disease. The bilateral parotid and submandibular glands and the thyroid gland are within normal limits. Visualized intracranial structures are unremarkable. Air-fluid level in the maxillary sinuses is consistent with acute sinusitis. The glottic and supraglottic larynx is within normal limits. Pharyngeal mucosal and parapharyngeal soft tissues are unremarkable.

CHEST:

The airways are clear. The lungs are clear. There is no pleural effusion or pneumothorax.

Heart size is within normal limits. There is calcified aortic and coronary artery atherosclerosis. There is no thoracic aortic aneurysm or dissection. There is no mediastinal, hilar, or axillary lymphadenopathy. There is no pericardial effusion.

Large hiatal hernia containing the gastric fundus is unchanged. Aberrant right subclavian artery arising distal to the origin of the left subclavian artery crosses midline posterior to the esophagus.

[page 13 of 15]
ABDOMEN/PELVIS:

The liver, gallbladder, spleen, pancreas, adrenal glands, and right kidney are unremarkable. Exophytic 10 mm left midpole benign renal cortical cyst is unchanged.

8 mm duodenal lipoma is unchanged. Small bowel is unremarkable. There is mild scattered colonic diverticulosis without evidence of diverticulitis. The appendix is within normal limits.

The uterus is surgically absent. There is possible circumferential symmetric bladder wall thickening with evaluation somewhat limited by underdistention of the bladder. There does appear to be mild circumferential perivesical inflammatory fat stranding, however.

There is no abdominal or pelvic lymphadenopathy. There is no free intraperitoneal fluid.

Bones are intact with no acute fracture or aggressive bone lesion.

There is aortic and iliac artery calcified atherosclerosis. There is no abdominal aortic aneurysm.

IMPRESSION:

1. Clear lungs with no evidence of recurrent or metastatic pulmonary or extrathoracic disease.
2. Apparent circumferential bladder wall thickening and perivesical inflammatory fat stranding suggest cystitis, although evaluation is somewhat limited by under distention of the urinary bladder. Clinical correlation is recommended.
3. Unchanged moderate hiatal hernia.

Electronically signed by [REDACTED]

Imaging Information

Exam Information

Performed Procedure
CT NECK CHEST ABD AND PELVIS W
CONTRAST

Study Status
Final

Begin Time

End Time

+1781

+1781

Staff Information

Order

CT NECK, CHEST, ABD, PELVIS (staging)

Print Result Report

[page 14 of 15]
report

Order

CT NECK CHEST ABD AND PELVIS W CONTRAST

CT NECK CHEST ABD AND PELVIS W CONTRAST Order # Spec.
#

Original Order Name (If blank, same as above):

CT NECK, CHEST, ABD, PELVIS (staging)

Encounter

View Parent Encounter

Order Information

[Redacted Order Information]

Order Questions

Question	Answer	Comment
Does patient have known reaction to IV contrast? (If yes, describe rx in comments and order pretreatment Smart RX)	NO	

Comments

CLINICAL CONCERN: Patient needs staging study. (differential diagnosis or r/o)

+1778 Wt Readings from Last 1 Encounters:
: 163 lb (73.936 kg)

Scheduling Instructions

[Redacted Scheduling Instructions]

[page 15 of 15]
Order Tracking Information

CT NECK, CHEST, ABD, PELVIS (staging)

+1781

Source: NCI Genomic Data Commons file efa68a69-f26a-4f25-b249-589e5afc2bd7 (ER0324 ER-ADJ2 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).